Surgical pathology report (de-identified scan), TCGA case TCGA-SQ-A6I4, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site International Genomics Consortium, specimen TCGA-SQ-A6I4-01A (Primary Tumor).

[page 1 of 2]
Results

GROSS AND MICROSCOPIC SURGICAL PANEL

Specimen Information

Collection Date and Time

Component Results

SURGICAL PANEL:

SURGICAL PATHOLOGY REPORT

LAB: [REDACTED]

Phone: [REDACTED]

Case# [REDACTED]

Final Report

DIAGNOSIS

A) RIGHT ADRENAL GLAND, ADRENALECTOMY:

1. Pheochromocytoma
- a. Tumor size 9.5 cm, 60 gm
- a. Surgical margins are negative for tumor
- c. No lymphatic invasion present
2. Residual adrenal gland with no diagnostic abnormality

COMMENT:

Malignancy in pheochromocytomas has been reported in 7 - 14% of cases, although malignancy in such tumors of adrenal origin may be closer to 2.4 - 2.8%. No histologic features of have been identified that definitively identify malignancy. The best evidence of malignancy is the presence of metastases in sites where non-neoplastic chromaffin tissue is not normally found. Please contact the [REDACTED] if you have questions regarding this case.

The tumor histology and immunoprofile (see microscopic) support the diagnosis.

Attending Pathologist: [REDACTED]

CLINICAL INFORMATION

Right adrenal mass

SPECIMEN/GROSS DESCRIPTION

A) SOURCE: Right adrenal gland

Received fresh labeled "rt adrenal gland" and consists of a 60 g, 10 x 7 x 3.3 cm adrenal gland with a moderate amount of attached fat. The specimen is entirely inked blue and the lateral aspect is overlaid with yellow, the medial aspect overlaid with green, superior is black, inferior is red.

The tissue is serially sectioned. In the inferior-medial aspect of the specimen is a there a 3.9 x 3.3 x 3.0 cm well circumscribed mass. The mass has a tan glistening rubbery cut surface with multiple hemorrhagic foci. It appears well circumscribed and extends to within 0.1 cm from the movable margins along the medial and inferior aspect of the specimen. It is unclear whether the lesion appears to arise from the cortical surface.

The remaining adrenal gland has orange cortical surface and brown medulla. The fat is tan-yellow and lobulated, no additional masses are noted.

Tissue is sampled for possible ancillary studies.

ICD-O-3
Pheochromocytoma NOS
8700/0
Site R Adrenal gland NOS
@ 74.9
JW6/12/13

[page 2 of 2]
Representative sections are submitted as follows:

1-7. Mass

8. Uninvolved adrenal gland

Gross dictation by:

MICROSCOPIC

The microscopic appearance substantiates the diagnosis.

Immunohistochemical staining:

Stain:	Block(s)	Result
Chromogranin	A2	Positive in tumor cells
Synaptophysin	A2	Positive in tumor cells
Inhibin	A2	Negative in tumor cells
Cytokeratin AE1/AE3	A2	Negative in tumor cells
Calretinin	A2	Positive in tumor cells
Melan A	A2	Negative in tumor cells

Reference:

1: A tissue microarray-based comparative analysis of novel and traditional immunohistochemical markers in the distinction between adrenal cortical lesions and pheochromocytoma.

Dictation by: ; transcribed by:

COLLECTED:

ACCESSIONED:

SIGNED:

Lab and Collection

Information

Result History

Lab Status

Order Complete

Result Information

Result Date and Time

Status
Final result

Provider Status
Reviewed

Lab Information

Order Details

Entry Date

H&A Discrepancy		✓
Prior Spontaneous Primary, Not d		✓
Revised	6/4/13	

Source: NCI Genomic Data Commons file bfee9488-a0e3-4aa8-ad23-44126fa4cb4e (TCGA-SQ-A6I4.B6F5CC0C-C16C-4CDF-B4B1-6A7DE7CF6471.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).